Somatic mutation profile of tumor specimen TCGA-SI-AA8C-01A (aliquot TCGA-SI-AA8C-01A-11D-A387-09) from TCGA case TCGA-SI-AA8C, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant peripheral nerve sheath tumor; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 20.6 years (7,530 days).
Specimen TCGA-SI-AA8C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b32dae0-a874-4a76-96f8-baf14b34355c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SI-AA8C-10A (Blood Derived Normal), aliquot TCGA-SI-AA8C-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0c7d6cf-1051-439b-bf0a-55d1602e8d7a

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 10, Silent 5, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPNE9 | c.1609C>T p.R537W | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); catalogued as COSV56069188; called by muse, mutect2, varscan2
- DLGAP2 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs748237600, COSV70097731; called by muse, mutect2, varscan2
- EVL | c.790G>A p.G264R (on ENST00000402714 / NM_001330221.2; = p.G266R on NM_016337.3) | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV101233113; called by muse, mutect2, varscan2
- KHDRBS2 | c.325G>C p.D109H | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55493458, COSV99028877, COSV99837140; called by muse, mutect2, varscan2
- PAXIP1 | c.2275G>A p.A759T | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101250053; called by muse, mutect2, varscan2
- PKHD1L1 | c.5192T>A p.V1731E | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as COSV101006767; called by muse, mutect2, varscan2
- RABGAP1L | c.1853G>C p.G618A | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99273844; called by muse, mutect2
- SEC31B | c.2700C>A p.N900K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.142); catalogued as COSV100947450; called by muse, mutect2
- USP46 | c.448A>G p.K150E | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT tolerated (0.66); PolyPhen benign (0.141); catalogued as COSV101484309; called by muse, mutect2, varscan2
- ZC3H7B | c.2300G>A p.R767H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs1271723038, COSV100687734; called by muse, varscan2
- SUZ12 | c.1722_1746del p.R575Vfs*10 | Frame Shift Del (DEL) | VAF 22/26 reads (85%) | called by mutect2, pindel
- DGKG | c.234C>A p.A78= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV99404297; called by muse, mutect2, varscan2
- FRMPD2 | c.1701C>A p.I567= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs772578849, COSV100564149; called by muse, mutect2, varscan2
- HS6ST3 | c.978T>A p.T326= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs759719846, COSV100941552; called by mutect2, varscan2
- KAZN | c.1980C>T p.I660= | Silent (SNP) | VAF 14/18 reads (78%) | catalogued as rs1051708781, COSV101057073, COSV65727305; called by muse, mutect2, varscan2
- PASD1 | c.336A>G p.L112= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as COSV100949583; called by muse, mutect2, varscan2
